Somatic mutation profile of tumor specimen TCGA-NJ-A4YF-01A (aliquot TCGA-NJ-A4YF-01A-12D-A25L-08) from TCGA case TCGA-NJ-A4YF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.9 years (18,584 days).
Specimen TCGA-NJ-A4YF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 751f6ac7-2f2a-4300-9ba4-87a92920d8bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A4YF-10A (Blood Derived Normal), aliquot TCGA-NJ-A4YF-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01e89769-e754-4eca-a5a3-b1b72ac4953f

The open-access MAF lists 666 somatic variants for this specimen: 506 protein-altering or splice-affecting, 144 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 428, Silent 144, Nonsense Mutation 42, Frame Shift Del 15, Splice Site 14, RNA 6, Frame Shift Ins 5, Intron 5, Splice Region 2, 3'UTR 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 33/49 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012193, CM067471, COSV58820785; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4927G>T p.G1643C (on ENST00000272895 / NM_173076.3; = p.G1325C on NM_015657.3) | Missense Mutation (SNP) | VAF 100/159 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs759068959, COSV99787939; called by muse, mutect2, varscan2
- ABCA13 | c.3420G>T p.K1140N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV101329896; called by muse, mutect2
- ABT1 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99223078, COSV99223119; called by muse, mutect2, varscan2
- AC013489.1 | c.1633A>T p.M545L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99183822; called by muse, mutect2, varscan2
- ACCSL | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.176); catalogued as COSV101122140, COSV66579974; called by muse, mutect2, varscan2
- ACKR1 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100929448; called by muse, mutect2, varscan2
- ACTL7B | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012483; called by muse, mutect2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM10 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 48/84 reads (57%) | catalogued as COSV99545409; called by muse, mutect2, varscan2
- ADAM2 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as rs1286693782, COSV99696592; called by muse, mutect2, varscan2
- ADAMTS2 | c.2240G>C p.G747A | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280641; called by muse, mutect2, varscan2
- ADCY1 | c.2119del p.L707Wfs*35 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as COSV52033485; called by mutect2, pindel, varscan2
- ADCY2 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100601526, COSV57905553; called by muse, mutect2, varscan2
- ADGRB2 | c.4235A>T p.Y1412F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99925568; called by muse, mutect2, varscan2
- ADGRF2 | c.1526G>C p.S509T (on ENST00000296862 / NM_001368115.2; = p.S441T on NM_153839.7) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as COSV99730594; called by muse, mutect2, varscan2
- ADGRG3 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV100341983; called by muse, mutect2, varscan2
- AFF4 | c.2057G>C p.S686T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.95); catalogued as COSV99534493; called by muse, mutect2, varscan2
- AGA | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375663828, COSV99219337; called by muse, mutect2, varscan2
- ALPK2 | c.3160C>A p.Q1054K | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100864024; called by muse, mutect2
- AMELX | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100496984, COSV61636707; called by muse, mutect2
- AMY2B | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796156, COSV63716259; called by muse, mutect2, varscan2
- ANO4 | c.1420G>T p.A474S (on ENST00000392977 / NM_001286615.2; = p.A439S on NM_178826.4) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV54609507; called by muse, mutect2, varscan2
- ARGFX | c.842C>A p.A281E | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV100544054; called by muse, mutect2, varscan2
- ARHGEF2 | c.1918C>G p.L640V (on ENST00000361247 / NM_001162383.2; = p.L612V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as rs1415975727, COSV100559917; called by muse, mutect2, varscan2
- ARID1B | c.5896A>T p.I1966F | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99266653; called by muse, mutect2, varscan2
- ARMC12 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV55361864; called by muse, mutect2, varscan2
- ASF1B | c.41A>T p.N14I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99654202; called by muse, mutect2, varscan2
- ASIC2 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56772284; called by muse, mutect2, varscan2
- ATF7IP | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV99661098; called by muse, mutect2, varscan2
- ATG7 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374142073; called by muse, mutect2, varscan2
- ATOH1 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100024413; called by muse, mutect2, varscan2
- ATP6V0A4 | c.747C>A p.C249* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV59481180; called by muse, mutect2
- ATP8B4 | c.2781+1G>T p.X927_splice | Splice Site (SNP) | VAF 40/56 reads (71%) | catalogued as rs750066978, COSV52713028, COSV99463135; called by muse, mutect2, varscan2
- ATRNL1 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV100743855; called by muse, mutect2, varscan2
- B3GNT7 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99805812; called by muse, mutect2, varscan2
- B4GALT2 | c.684C>G p.Y228* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100530538; called by muse, mutect2, varscan2
- BCL11B | c.1745G>T p.G582V (on ENST00000357195 / NM_001282237.2; = p.G511V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100595071; called by muse, mutect2, varscan2
- BCR | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | catalogued as COSV100005861, COSV59929396; called by muse, mutect2, varscan2
- BEND2 | c.2360C>G p.S787* | Nonsense Mutation (SNP) | VAF 48/186 reads (26%) | catalogued as COSV101192573; called by muse, mutect2, varscan2
- BRAT1 | c.2218A>T p.R740W | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100500290; called by muse, mutect2, varscan2
- BRCA1 | c.2119G>C p.G707R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs587781420, COSV100523180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100324602; called by muse, mutect2, varscan2
- BRINP3 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs745308648, COSV100818636, COSV66522732; called by muse, mutect2, varscan2
- BRINP3 | c.330C>G p.N110K | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100818196, COSV66511378; called by muse, mutect2, varscan2
- BTBD16 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53261021, COSV99584446; called by muse, mutect2, varscan2
- BUD13 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 197/288 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV99496188; called by muse, mutect2, varscan2
- C3orf70 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100621110; called by muse, mutect2, varscan2
- CACNA1G | c.4134G>T p.R1378S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100661056; called by muse, mutect2, varscan2
- CALCRL | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101130865, COSV99061579; called by muse, mutect2
- CAMSAP2 | c.981G>T p.M327I (on ENST00000236925 / NM_001297707.2; = p.M316I on NM_203459.3) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.263); catalogued as COSV99372756; called by muse, mutect2, varscan2
- CARD9 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as COSV100260851; called by muse, mutect2
- CBLN4 | c.197C>A p.A66E | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs749471305, COSV50353675, COSV99290307; called by muse, mutect2
- CCDC80 | c.1693A>T p.S565C | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99244140; called by muse, mutect2, varscan2
- CD1E | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63772780; called by muse, mutect2, varscan2
- CDH11 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216933; called by muse, mutect2, varscan2
- CDH12 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101200838, COSV66444733; called by muse, mutect2, varscan2
- CDH17 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99216862; called by muse, mutect2, varscan2
- CDK5RAP3 | c.936G>C p.W312C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621076; called by muse, mutect2, varscan2
- CDX2 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV101122644, COSV101122645; called by muse, mutect2, varscan2
- CDX4 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100999101; called by muse, mutect2, varscan2
- CEACAM20 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100386754; called by muse, mutect2, varscan2
- CFAP69 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV100289699; called by muse, mutect2, varscan2
- CHD1L | c.1385A>T p.K462M | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100787288; called by muse, mutect2, varscan2
- CHD2 | c.2109A>T p.K703N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101244627; called by muse, mutect2, varscan2
- CHD5 | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV99312174; called by muse, mutect2, varscan2
- CHORDC1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271829; called by muse, mutect2, varscan2
- CHRM2 | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as COSV100280591; called by muse, mutect2, varscan2
- CLEC10A | c.565C>A p.Q189K (on ENST00000254868 / NM_182906.4; = p.Q165K on NM_006344.4) | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99644503; called by muse, mutect2, varscan2
- CNTN5 | c.1352C>A p.S451* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99672061, COSV99674012; called by muse, mutect2, varscan2
- CNTN5 | c.2492C>A p.A831D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99672064; called by muse, mutect2, varscan2
- COL14A1 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV99917711; called by muse, mutect2, varscan2
- COL16A1 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99593391; called by muse, mutect2, varscan2
- COL3A1 | c.4000G>A p.G1334S | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV100482308; called by muse, mutect2, varscan2
- COLGALT2 | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100730328; called by muse, varscan2
- CORIN | c.1388G>C p.C463S | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99902720; called by muse, mutect2, varscan2
- CPEB1 | c.1385G>T p.R462L (on ENST00000617958; = p.R397L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99917357; called by muse, mutect2, varscan2
- CPNE6 | c.348+2T>A p.X116_splice | Splice Site (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99393036; called by muse, mutect2, varscan2
- CR1 | c.3421C>A p.P1141T | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100887343; called by muse, mutect2, varscan2
- CR1 | c.3422C>A p.P1141Q | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100887344; called by muse, mutect2, varscan2
- CRB1 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958243; called by muse, mutect2, varscan2
- CRB1 | c.2057G>C p.R686P | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1281817527, COSV100957623; called by muse, mutect2, varscan2
- CRISPLD1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV51545666, COSV51546514; called by muse, mutect2, varscan2
- CSMD1 | c.7594C>A p.Q2532K (on ENST00000520002; = p.Q2531K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.131); catalogued as COSV100142376; called by muse, mutect2
- CSMD3 | c.8188C>A p.H2730N | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99822285, COSV99830328; called by muse, mutect2, varscan2
- CSMD3 | c.5231G>C p.G1744A (on ENST00000297405 / NM_001363185.1; = p.G1640A on NM_052900.3) | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV52146370, COSV99822288; called by muse, mutect2, varscan2
- CSMD3 | c.2070C>A p.C690* (on ENST00000297405 / NM_001363185.1; = p.C586* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 51/514 reads (10%) | catalogued as COSV99822290; called by muse, mutect2, varscan2
- CSMD3 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99822292; called by muse, mutect2, varscan2
- CTDSP1 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99811836; called by muse, mutect2, varscan2
- CTNNA2 | c.2428G>T p.G810W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559258; called by muse, mutect2, varscan2
- CTNND2 | c.2105G>T p.R702L | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100470772, COSV58878402; called by muse, mutect2, varscan2
- CUEDC1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774433170, COSV100804635; called by muse, mutect2, varscan2
- CUX2 | c.3244G>T p.V1082L | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55624737, COSV99918424; called by muse, mutect2, varscan2
- CYYR1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.013); catalogued as COSV100176417; called by muse, mutect2, varscan2
- DAPK1 | c.1415A>C p.N472T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100800817; called by muse, mutect2, varscan2
- DCC | c.2643C>A p.Y881* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100497710; called by muse, mutect2, varscan2
- DCLK1 | c.2105A>G p.N702S (on ENST00000360631 / NM_001330072.2; = p.T727A on NM_004734.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); catalogued as COSV55190219; called by muse, mutect2, varscan2
- DCSTAMP | c.1271T>G p.L424R | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99885989; called by muse, mutect2
- DDX10 | c.532G>T p.G178* | Nonsense Mutation (SNP) | VAF 82/221 reads (37%) | catalogued as COSV100488915; called by muse, mutect2, varscan2
- DDX19B | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV99849750; called by muse, mutect2, varscan2
- DDX23 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100339536; called by muse, mutect2, varscan2
- DENND1B | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99343627; called by muse, mutect2, varscan2
- DGCR8 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61226997; called by muse, mutect2, varscan2
- DIAPH2 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100230291; called by muse, mutect2, varscan2
- DIAPH2 | c.2254G>T p.V752L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV100230295; called by muse, mutect2
- DISC1 | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV99696968; called by muse, mutect2, varscan2
- DMD | c.3805C>A p.H1269N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100817349, COSV63765106; called by muse, mutect2, varscan2
- DMRT3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV99505621; called by muse, mutect2, varscan2
- DMXL1 | c.5740G>T p.A1914S | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100223068; called by muse, mutect2, varscan2
- DNAH3 | c.8081C>A p.A2694E | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); catalogued as rs372944277, COSV99764565; called by muse, mutect2, varscan2
- DNAH3 | c.8080G>A p.A2694T | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99764566; called by muse, mutect2, varscan2
- DNAH9 | c.12953C>A p.A4318E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99303462; called by muse, mutect2, varscan2
- DST | c.7397G>T p.G2466V | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as COSV99750124; called by muse, mutect2, varscan2
- EGFLAM | c.2818A>T p.T940S (on ENST00000354891 / NM_001205301.2; = p.T932S on NM_152403.4) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV100379680; called by muse, mutect2, varscan2
- EIF4G1 | c.1608+1G>C p.X536_splice (on ENST00000346169 / NM_198241.3; = p.X340_splice on NM_004953.5) | Splice Site (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100071370; called by muse, mutect2, varscan2
- EIF5B | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.219); catalogued as COSV99176748; called by muse, mutect2, varscan2
- ELF1 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522788; called by muse, mutect2, varscan2
- ENAM | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101252887, COSV68536735; called by muse, mutect2, varscan2
- EPHA4 | c.2198G>T p.G733V | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99915277; called by muse, mutect2, varscan2
- EPHA6 | c.2046G>T p.K682N (on ENST00000389672 / NM_001080448.3; = p.K74N on NM_173655.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101060625; called by muse, mutect2, varscan2
- EPS8L3 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs77987176, COSV100719646; called by muse, mutect2, varscan2
- EPS8L3 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100719647; called by muse, mutect2, varscan2
- ERICH3 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100443197; called by muse, mutect2, varscan2
- EVC2 | c.2483G>C p.W828S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100184836; called by muse, mutect2, varscan2
- F13A1 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99341974; called by muse, mutect2
- FAM135B | c.3577C>G p.R1193G | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52715961, COSV99417794; called by muse, mutect2
- FAM155B | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs866457481, COSV99368086, COSV99368099; called by muse, mutect2, varscan2
- FAM9C | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100452752; called by muse, mutect2, varscan2
- FANCB | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100146315; called by muse, mutect2, varscan2
- FASLG | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100390326; called by muse, mutect2, varscan2
- FAT2 | c.6377C>T p.S2126L | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99941451; called by muse, mutect2, varscan2
- FAT3 | c.2539G>C p.G847R | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99960926; called by muse, mutect2, varscan2
- FAT3 | c.3716G>T p.W1239L | Missense Mutation (SNP) | VAF 193/376 reads (51%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99960932; called by muse, mutect2, varscan2
- FAT3 | c.6517G>C p.E2173Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99960940; called by muse, mutect2, varscan2
- FAT3 | c.12208C>T p.R4070W | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs760090138, COSV53131365; called by muse, mutect2, varscan2
- FCRL1 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322772805, COSV100839700; called by muse, mutect2, varscan2
- FER1L6 | c.2798C>G p.P933R | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101205329; called by muse, mutect2
- FHOD3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV99939848; called by muse, mutect2, varscan2
- FLG | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 438/951 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); catalogued as COSV100910386; called by muse, mutect2, varscan2
- FLG | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 231/553 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV100910387; called by muse, mutect2, varscan2
- FLG | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759559864, COSV100910388; called by muse, mutect2, varscan2
- FLNC | c.4612G>A p.D1538N | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100367537, COSV57957201; called by muse, mutect2, varscan2
- FNBP4 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771363; called by muse, mutect2, varscan2
- FNDC3B | c.2413G>T p.G805* | Nonsense Mutation (SNP) | VAF 21/225 reads (9%) | catalogued as COSV100393430; called by muse, mutect2
- FRMD7 | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100048630; called by muse, mutect2, varscan2
- FRMD7 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.802); catalogued as COSV100048631; called by muse, mutect2, varscan2
- FRMPD1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV100899233; called by muse, mutect2, varscan2
- FSTL1 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99820426; called by muse, mutect2, varscan2
- FYCO1 | c.4082G>T p.G1361V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99945067; called by muse, mutect2, varscan2
- GAB4 | c.1709G>T p.R570M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs747680100, COSV101271857; called by muse, mutect2, varscan2
- GABRB3 | c.956T>A p.L319Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100157847; called by muse, mutect2, varscan2
- GABRG3 | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100404185; called by muse, mutect2
- GABRG3 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 88/160 reads (55%) | catalogued as rs75880610, COSV61520902; called by muse, mutect2
- GABRG3 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100404195; called by muse, mutect2, varscan2
- GABRR1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101033710, COSV101033839; called by muse, mutect2, varscan2
- GANC | c.76A>T p.K26* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100213135; called by muse, mutect2, varscan2
- GJA9 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100668027; called by muse, mutect2, varscan2
- GMEB1 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99602895; called by muse, mutect2, varscan2
- GOLGB1 | c.9127C>T p.Q3043* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100510239; called by muse, mutect2, varscan2
- GOLGB1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs758640097, COSV100510240; called by muse, mutect2, varscan2
- GPATCH8 | c.2870G>T p.R957L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100132406; called by muse, mutect2, varscan2
- GPR141 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV100550204; called by muse, mutect2, varscan2
- GPR17 | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.32); catalogued as COSV99760378; called by muse, mutect2, varscan2
- GPR88 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1422172696, COSV100159397; called by muse, mutect2, varscan2
- GRID1 | c.2243A>T p.Y748F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100021418, COSV60042884; called by muse, mutect2, varscan2
- GRIN1 | c.940A>T p.I314F | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100159723; called by muse, mutect2, varscan2
- GSR | c.802A>T p.R268* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99645296; called by muse, mutect2, varscan2
- GYG1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936672; called by muse, mutect2, varscan2
- H1-5 | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100137666; called by muse, mutect2, varscan2
- HGF | c.1928G>T p.S643I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV55958198, COSV99735269; called by muse, mutect2, varscan2
- HGF | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99735271; called by muse, mutect2, varscan2
- HHIP | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs1391381557, COSV99666486; called by muse, mutect2, varscan2
- HHIPL1 | c.656G>T p.W219L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100414925; called by muse, mutect2, varscan2
- HIP1 | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100416812; called by muse, mutect2, varscan2
- HOXA3 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100415265; called by muse, mutect2, varscan2
- HRG | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV99214495; called by muse, mutect2, varscan2
- HTR3B | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99491695; called by muse, mutect2, varscan2
- HUS1 | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99346375; called by muse, mutect2, varscan2
- IDE | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV99793734; called by muse, mutect2
- IFT172 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1401986067, COSV53141130; called by muse, mutect2, varscan2
- IGKV2-28 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs1204729100; called by muse, mutect2, varscan2
- IGKV2D-28 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV101494549; called by mutect2, varscan2
- IRS4 | c.2072C>A p.A691D | Missense Mutation (SNP) | VAF 162/317 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV100929394; called by muse, mutect2, varscan2
- ITGA8 | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65229292; called by muse, mutect2, varscan2
- JAKMIP1 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV51546116, COSV99288454; called by muse, mutect2
- JAKMIP2 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99507193; called by muse, mutect2, varscan2
- JCAD | c.903C>G p.H301Q | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV100948019; called by muse, mutect2, varscan2
- KALRN | c.4390G>C p.G1464R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561801; called by muse, mutect2, varscan2
- KALRN | c.6213G>A p.K2071= (on ENST00000360013 / NM_001024660.4; = p.K374= on NM_007064.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99360854; called by muse, mutect2, varscan2
- KBTBD3 | c.1335C>G p.Y445* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | catalogued as COSV101595657; called by muse, mutect2, varscan2
- KCNA4 | c.1604T>A p.V535E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100068432, COSV100068913; called by muse, mutect2, varscan2
- KCNE2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV99285640; called by muse, mutect2, varscan2
- KCNH5 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV100525085; called by muse, mutect2, varscan2
- KCNJ16 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99387857; called by muse, mutect2, varscan2
- KCNJ2 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99696158; called by muse, mutect2, varscan2
- KCNT1 | c.2673-1G>T p.X891_splice (on ENST00000488444; = p.X910_splice on NM_020822.3) | Splice Site (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99704781; called by muse, mutect2, varscan2
- KEL | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs911607332, COSV100786828, COSV62337758; called by muse, mutect2, varscan2
- KIAA0895L | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99220346; called by muse, mutect2, varscan2
- KIF14 | c.3057A>T p.E1019D | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100950575; called by muse, mutect2, varscan2
- KIF27 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs779723498, COSV99926539; called by muse, mutect2, varscan2
- KLB | c.1757T>C p.L586P | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99961893; called by muse, mutect2, varscan2
- KLHDC7A | c.1568G>C p.R523P | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs769964876, COSV101272700, COSV68769002; called by muse, mutect2, varscan2
- KNL1 | c.6673-1G>T p.X2225_splice (on ENST00000346991 / NM_170589.5; = p.X2199_splice on NM_144508.5) | Splice Site (SNP) | VAF 26/116 reads (22%) | catalogued as COSV100705801; called by muse, mutect2, varscan2
- KRBA1 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752124; called by mutect2, varscan2
- KRT27 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100053150; called by muse, mutect2, varscan2
- KRT34 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.124); catalogued as rs139913573, COSV101222525; called by muse, mutect2, varscan2
- KRT6B | c.126G>T p.R42S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99360379; called by muse, mutect2, varscan2
- KRTAP10-4 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100551584; called by muse, mutect2, varscan2
- KRTAP5-10 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 65/168 reads (39%) | PolyPhen possibly damaging (0.839); catalogued as COSV100924119; called by muse, mutect2, varscan2
- LAMP5 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1321183696, COSV99855406; called by muse, mutect2, varscan2
- LATS2 | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231438; called by muse, mutect2, varscan2
- LEPR | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100847787; called by muse, mutect2, varscan2
- LGR5 | c.338T>A p.L113H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99877371; called by muse, mutect2, varscan2
- LPA | c.3947+1G>T p.X1316_splice | Splice Site (SNP) | VAF 35/85 reads (41%) | catalogued as rs1032955724, COSV100305908; called by muse, mutect2, varscan2
- LRIT1 | c.1396T>G p.F466V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100927987; called by muse, mutect2, varscan2
- LRP1B | c.11003A>T p.E3668V | Missense Mutation (SNP) | VAF 125/321 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101250984; called by muse, varscan2
- LRP1B | c.7832A>T p.N2611I | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101250985; called by muse, varscan2
- LRP1B | c.7802G>T p.G2601V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101250987, COSV67213525; called by muse, varscan2
- LRP1B | c.3151G>T p.A1051S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.505); catalogued as COSV101250989; called by muse, mutect2, varscan2
- LRRC42 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV100066232, COSV59960239, COSV59960522; called by muse, mutect2, varscan2
- LRRIQ4 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.749); catalogued as COSV100540044, COSV61618693; called by muse, mutect2, varscan2
- MACF1 | c.8649G>T p.L2883F | Missense Mutation (SNP) | VAF 7/94 reads (7%) | catalogued as COSV99240717; called by muse, mutect2
- MAGEB16 | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101303265; called by muse, mutect2, varscan2
- MAGEB18 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV100305264; called by muse, mutect2, varscan2
- MAGI2 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100832142; called by muse, mutect2
- MAGT1 | c.502C>T p.R168W (on ENST00000618282 / NM_001367916.1; = p.R200W on NM_032121.5) | Missense Mutation (SNP) | VAF 127/201 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs372142118, CD143814, COSV63781696; called by muse, mutect2, varscan2
- MAML2 | c.3416A>G p.N1139S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV101593928; called by muse, mutect2
- MAMLD1 | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 156/248 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99475463; called by muse, mutect2, varscan2
- MAP1A | c.5005C>A p.P1669T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV100287966; called by muse, mutect2, varscan2
- MAP4K4 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100153302; called by muse, mutect2, varscan2
- MBOAT1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100208319; called by muse, mutect2, varscan2
- MCM2 | c.1393A>T p.T465S | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV99412708; called by muse, mutect2, varscan2
- MDGA2 | c.3011G>T p.G1004V (on ENST00000399232 / NM_001113498.2; = p.G706V on NM_182830.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); catalogued as COSV100636139; called by muse, mutect2, varscan2
- MDGA2 | c.3010G>T p.G1004W (on ENST00000399232 / NM_001113498.2; = p.G706W on NM_182830.4) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV62104882, COSV62112919; called by muse, mutect2, varscan2
- MEGF6 | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99619224; called by muse, mutect2, varscan2
- MICU1 | c.1089G>C p.E363D (on ENST00000361114 / NM_001195518.2; = p.E369D on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0.147); catalogued as COSV100741596; called by muse, mutect2, varscan2
- MICU3 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100536007; called by muse, mutect2, varscan2
- MITF | c.732G>T p.M244I (on ENST00000448226 / NM_006722.3; = p.M138I on NM_000248.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV100096394; called by muse, mutect2, varscan2
- MLIP | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99228231, COSV99230214, COSV99230369; called by muse, mutect2
- MRPL42 | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100696578; called by muse, mutect2, varscan2
- MSI2 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52363421, COSV99401460; called by muse, mutect2
- MUC16 | c.30673G>T p.V10225L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.142); catalogued as COSV101197729; called by muse, mutect2, varscan2
- MUC16 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as rs1222761973, COSV67477107; called by muse, mutect2, varscan2
- MYBPC1 | c.2237C>A p.A746E (on ENST00000550270 / NM_206820.2; = p.A771E on NM_002465.4) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637694; called by muse, mutect2, varscan2
- MYH1 | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 86/149 reads (58%) | catalogued as COSV99874712; called by muse, mutect2, varscan2
- MYH10 | c.531-1G>T p.X177_splice | Splice Site (SNP) | VAF 51/90 reads (57%) | catalogued as COSV99343885; called by muse, mutect2, varscan2
- MYH15 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as COSV99842026; called by muse, mutect2, varscan2
- MYH4 | c.2985G>T p.K995N | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99700212; called by muse, mutect2, varscan2
- MYH7B | c.715G>C p.A239P | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53424913, COSV99482190; called by muse, mutect2, varscan2
- MYO1A | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV100270491; called by muse, mutect2, varscan2
- MYO3B | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 82/142 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs753265274, COSV100508992; called by muse, mutect2, varscan2
- NBPF3 | c.359A>T p.K120I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100558331; called by muse, mutect2, varscan2
- NCK2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99028477, COSV99256327; called by muse, mutect2, varscan2
- NCOA1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs751626907, COSV99945016; called by muse, mutect2, varscan2
- NDE1 | c.1090G>T p.E364* (on ENST00000577101; = p.*336Lext*11 on NM_017668.3) | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100257503; called by muse, mutect2, varscan2
- NDUFAF6 | c.777A>G p.I259M | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV99712569; called by muse, mutect2, varscan2
- NECAB1 | c.868A>T p.I290L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV101340989, COSV70236673; called by muse, mutect2, varscan2
- NEK11 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172304184, COSV100797552; called by mutect2, varscan2
- NELL2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs1217580926, COSV100418505; called by muse, mutect2, varscan2
- NLRP3 | c.2871G>A p.W957* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100275129; called by muse, mutect2, varscan2
- NLRP7 | c.999C>A p.F333L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100051496, COSV60176692; called by muse, mutect2, varscan2
- NME8 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99552671; called by muse, mutect2, varscan2
- NOS1AP | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV100722759; called by muse, mutect2, varscan2
- NOX3 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342586; called by muse, mutect2, varscan2
- NRXN3 | c.637A>G p.I213V (on ENST00000557594 / NM_001272020.2; = p.I845V on NM_004796.6) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV99815136; called by muse, mutect2, varscan2
- NUP133 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99772492; called by muse, mutect2, varscan2
- ONECUT1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100008977; called by muse, mutect2, varscan2
- OPLAH | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV101470703; called by muse, mutect2, varscan2
- OR10A7 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100406497; called by muse, mutect2, varscan2
- OR13A1 | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980956; called by muse, mutect2, varscan2
- OR13D1 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100598626; called by muse, varscan2
- OR1N2 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs758154524, COSV101031319; called by muse, mutect2, varscan2
- OR2A2 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV101286610; called by muse, mutect2, varscan2
- OR2L8 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 112/739 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100594010; called by muse, mutect2, varscan2
- OR2L8 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 112/742 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100594011, COSV61727878; called by muse, mutect2, varscan2
- OR2M3 | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs748575324, COSV101513390, COSV71758967; called by muse, mutect2
- OR2M4 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV100140935; called by muse, mutect2, varscan2
- OR2T27 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV100788092; called by muse, mutect2
- OR4D6 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.05); catalogued as COSV100271530; called by muse, mutect2, varscan2
- OR52N4 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); catalogued as COSV100421555; called by muse, mutect2, varscan2
- OR5L2 | c.340del p.L114Cfs*4 | Frame Shift Del (DEL) | VAF 89/298 reads (30%) | catalogued as COSV65723992; called by mutect2, pindel, varscan2
- OR5M8 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367675550; called by muse, mutect2, varscan2
- OR5T1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as COSV100478665; called by muse, mutect2, varscan2
- OR5T3 | c.850A>T p.I284F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100282650, COSV57383065; called by muse, mutect2, varscan2
- OR6K2 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100656662, COSV100656758; called by muse, mutect2, varscan2
- OR6Y1 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV56929837; called by muse, mutect2, varscan2
- OR7C2 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV99934376; called by muse, mutect2, varscan2
- OR8K3 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs768658746, COSV100449637, COSV57131577; called by muse, mutect2
- OR8K5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57888540; called by muse, mutect2, varscan2
- OR8U1 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100163708; called by muse, varscan2
- P2RX5 | c.306dup p.V103Cfs*18 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs762589989; called by mutect2, pindel, varscan2
- PACRG | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100433051; called by muse, mutect2, varscan2
- PARD3B | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370702778, COSV100591885; called by muse, mutect2, varscan2
- PARD3B | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 92/128 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100591889; called by muse, mutect2, varscan2
- PAX2 | c.689T>C p.V230A (on ENST00000428433 / NM_003987.5; = p.V207A on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV100694917; called by muse, mutect2, varscan2
- PAX5 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254060202, COSV100813996; called by muse, mutect2, varscan2
- PCDH11X | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100007461; called by muse, mutect2, varscan2
- PCDH15 | c.4791T>A p.S1597R (on ENST00000644397 / NM_001354429.2; = p.S1539R on NM_001142771.2) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); catalogued as COSV100902429; called by muse, mutect2, varscan2
- PCDH15 | c.5263C>A p.P1755T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.014); catalogued as rs768408753, COSV100214046, COSV100225830; called by muse, mutect2, varscan2
- PCDH17 | c.3123G>T p.K1041N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as COSV100931385; called by muse, mutect2, varscan2
- PCDH19 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55257310, COSV99718888; called by muse, mutect2, varscan2
- PCDHA5 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV100972064, COSV65353025; called by muse, mutect2, varscan2
- PCDHB12 | c.1634C>A p.A545E | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1340140236, COSV53399610, COSV99506596; called by muse, mutect2, varscan2
- PCDHGA4 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV99529105; called by muse, mutect2, varscan2
- PCDHGB3 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 93/153 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV53949549; called by muse, mutect2, varscan2
- PCDHGB4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529108; called by muse, mutect2, varscan2
- PCK1 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100099915; called by muse, mutect2, varscan2
- PCLO | c.13707A>T p.E4569D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100426661; called by muse, mutect2, varscan2
- PCLO | c.9736del p.R3246Efs*18 | Frame Shift Del (DEL) | VAF 29/131 reads (22%) | catalogued as COSV61628061; called by mutect2, pindel, varscan2
- PCNX2 | c.5464G>C p.D1822H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50785775, COSV99265698; called by muse, mutect2, varscan2
- PCNX4 | c.1717T>A p.S573T (on ENST00000406854 / NM_001330177.2; = p.S339T on NM_022495.5) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100469732; called by muse, mutect2, varscan2
- PDE1C | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.916); catalogued as COSV101275350; called by muse, mutect2, varscan2
- PDE4DIP | c.3463G>T p.G1155C | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100516037; called by muse, mutect2, varscan2
- PEX5L | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV99827762, COSV99829128; called by muse, mutect2, varscan2
- PF4V1 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99896276; called by muse, mutect2, varscan2
- PGK2 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505294, COSV59163920; called by muse, mutect2, varscan2
- PHF2 | c.159T>G p.C53W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100822976, COSV63678288; called by muse, varscan2
- PHF2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100822977; called by muse, varscan2
- PIK3C2B | c.2896C>T p.Q966* | Nonsense Mutation (SNP) | VAF 70/234 reads (30%) | catalogued as COSV65809043; called by muse, mutect2, varscan2
- PKD2 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as rs377704618; called by muse, mutect2, varscan2
- PKHD1 | c.5669C>A p.A1890E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100580820; called by muse, mutect2, varscan2
- PKHD1 | c.4552G>T p.V1518L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs754102295, COSV100580821; called by muse, mutect2, varscan2
- PKHD1L1 | c.7528C>A p.H2510N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV65740323; called by muse, mutect2, varscan2
- PLA2G4A | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 63/176 reads (36%) | catalogued as COSV100820331; called by muse, mutect2, varscan2
- PLCG1 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV54823394, COSV99718391; called by muse, mutect2, varscan2
- PLSCR2 | c.428G>T p.G143V (on ENST00000497985 / NM_001199978.1; = p.G70V on NM_020359.2) | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99072491; called by muse, mutect2, varscan2
- PLSCR5 | c.698C>A p.A233D | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101494459; called by muse, mutect2, varscan2
- POLR3A | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 117/211 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100965517; called by muse, mutect2, varscan2
- PON1 | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV99731903; called by muse, mutect2, varscan2
- POP1 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV100855605; called by muse, mutect2, varscan2
- POPDC2 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV99950794; called by muse, mutect2, varscan2
- PPIAL4G | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1553321444, COSV101343984; called by muse, mutect2, varscan2
- PPP1CB | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV56091054; called by muse, mutect2
- PRDM14 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52570681, COSV99399817; called by muse, mutect2
- PRELID3A | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100426810; called by muse, mutect2, varscan2
- PRG4 | c.1981C>A p.P661T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.115); catalogued as COSV100798082; called by muse, varscan2
- PRKCA | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99433437; called by muse, mutect2, varscan2
- PRPF19 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99920422; called by muse, mutect2, varscan2
- PRPS1 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100978832; called by muse, mutect2, varscan2
- PRRG1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1421209172, COSV66158811; called by muse, mutect2, varscan2
- PRSS58 | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV101616076; called by muse, mutect2, varscan2
- PRUNE2 | c.8589G>T p.E2863D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99795831; called by muse, mutect2
- PRUNE2 | c.6634C>A p.P2212T | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100944176; called by muse, mutect2, varscan2
- PSAPL1 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV100040265; called by muse, mutect2, varscan2
- PSMG1 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100312651; called by muse, mutect2, varscan2
- PTGDS | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1278604696, COSV56400676; called by muse, mutect2
- PTGFRN | c.1911G>T p.E637D | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101277229, COSV101277247; called by muse, mutect2, varscan2
- PTGS1 | c.212-1G>T p.X71_splice | Splice Site (SNP) | VAF 23/231 reads (10%) | catalogued as COSV99792847; called by muse, mutect2
- PTPN13 | c.3533C>T p.P1178L (on ENST00000411767 / NM_080683.3; = p.P1159L on NM_006264.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363889; called by muse, mutect2
- PTPRB | c.1824C>G p.Y608* | Nonsense Mutation (SNP) | VAF 39/191 reads (20%) | catalogued as COSV99715467; called by muse, mutect2, varscan2
- PTPRD | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100642816, COSV61995148; called by muse, mutect2, varscan2
- PTPRD | c.568+1G>T p.X190_splice | Splice Site (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100642819; called by muse, mutect2, varscan2
- PTPRN | c.2218C>A p.H740N | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99833602; called by muse, mutect2, varscan2
- PTPRN2 | c.1361A>T p.K454I | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV101233458; called by muse, mutect2, varscan2
- PTPRR | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs965630984, COSV99315926; called by muse, mutect2, varscan2
- PTPRT | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100624601, COSV62024441; called by muse, mutect2, varscan2
- PTPRT | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 68/95 reads (72%) | catalogued as COSV100624602; called by muse, mutect2, varscan2
- PUM3 | c.1564G>T p.V522F | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV101146253; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1879G>T p.G627* | Nonsense Mutation (SNP) | VAF 42/211 reads (20%) | catalogued as COSV99769614; called by muse, mutect2, varscan2
- RASGRF2 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99428345; called by muse, mutect2, varscan2
- REG1A | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as COSV99286628; called by muse, mutect2, varscan2
- RELN | c.4919T>C p.I1640T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100632057; called by muse, mutect2
- RGS7BP | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100470276, COSV61835148; called by muse, mutect2, varscan2
- RHBDF2 | c.1744A>T p.R582W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99166166; called by muse, mutect2
- RHBDF2 | c.1742C>A p.A581D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456632940, COSV99166167; called by muse, mutect2
- RHCE | c.761C>A p.S254* | Nonsense Mutation (SNP) | VAF 46/171 reads (27%) | catalogued as COSV99603679; called by muse, varscan2
- RIF1 | c.4699A>C p.K1567Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99689943; called by muse, mutect2, varscan2
- RIMKLB | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100223710; called by muse, mutect2, varscan2
- RIMS1 | c.4097C>T p.S1366L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99323300; called by muse, mutect2, varscan2
- RIMS2 | c.856G>A p.E286K (on ENST00000666250 / NM_001348490.2; = p.E94K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99155744, COSV99191733; called by muse, mutect2, varscan2
- RINT1 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99994169; called by muse, mutect2, varscan2
- RNF133 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411409; called by muse, mutect2, varscan2
- RNF20 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100874291; called by muse, mutect2, varscan2
- RNF213 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV100172902; called by muse, mutect2, varscan2
- RNF40 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100221856; called by muse, mutect2, varscan2
- RPAIN | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV100506715; called by muse, mutect2, varscan2
- RSAD1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364078; called by muse, mutect2, varscan2
- RTF2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99196446; called by muse, mutect2
- RUBCN | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99583008; called by muse, mutect2, varscan2
- RYR1 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as rs1202941571, COSV62098958; called by muse, mutect2
- RYR2 | c.1103C>A p.T368K | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100767333; called by muse, mutect2, varscan2
- RYR2 | c.10339C>G p.Q3447E | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as COSV100767334, COSV63675852; called by muse, mutect2, varscan2
- RYR2 | c.11077G>T p.D3693Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100767335; called by muse, mutect2, varscan2
- SCFD2 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101189204; called by muse, mutect2, varscan2
- SCN2A | c.2143A>T p.M715L | Missense Mutation (SNP) | VAF 88/143 reads (62%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99329864; called by muse, mutect2, varscan2
- SCNN1B | c.194G>T p.W65L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100225312; called by muse, mutect2, varscan2
- SCPEP1 | c.1297-2A>T p.X433_splice | Splice Site (SNP) | VAF 52/128 reads (41%) | catalogued as COSV99227642; called by muse, mutect2, varscan2
- SDK1 | c.4004C>G p.T1335R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV101268661; called by muse, mutect2, varscan2
- SERPINE1 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.355); catalogued as COSV99776548; called by muse, mutect2, varscan2
- SETX | c.7798C>T p.H2600Y | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1435277059, COSV99808627; called by muse, varscan2
- SHCBP1L | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100840915; called by muse, mutect2, varscan2
- SI | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs1468782357, COSV100013606; called by muse, mutect2, varscan2
- SIGLEC12 | c.640G>T p.E214* (on ENST00000291707 / NM_053003.4; = p.E96* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 69/137 reads (50%) | catalogued as COSV99388999; called by muse, mutect2, varscan2
- SLC22A25 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs756676547, COSV100123385; called by muse, mutect2, varscan2
- SLC24A2 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99645626; called by muse, mutect2, varscan2
- SLC26A7 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99402353; called by muse, mutect2
- SLC36A2 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58862671; called by muse, mutect2, varscan2
- SLC44A5 | c.854-2A>T p.X285_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100900865; called by muse, mutect2
- SLC45A2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99672235; called by muse, mutect2, varscan2
- SLC6A20 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV62070217; called by muse, mutect2
- SLC7A3 | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99979271; called by muse, mutect2, varscan2
- SLCO1A2 | c.1074G>T p.M358I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100261233; called by muse, mutect2, varscan2
- SLU7 | c.1627A>G p.M543V | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99775416; called by muse, mutect2, varscan2
- SMARCC2 | c.3139G>T p.G1047C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); catalogued as COSV99519196; called by muse, mutect2, varscan2
- SMC2 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV99658199; called by muse, mutect2, varscan2
- SMPD1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV100192256; called by muse, mutect2, varscan2
- SMR3A | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.616); catalogued as COSV99895465; called by muse, mutect2, varscan2
- SNTG1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52435494; called by muse, mutect2, varscan2
- SPAG17 | c.3132dup p.Q1045Afs*3 | Frame Shift Ins (INS) | VAF 13/79 reads (16%) | catalogued as rs1378132602; called by mutect2, pindel, varscan2
- SPAG6 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV100509886; called by muse, mutect2, varscan2
- SPATA31D1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV61202934; called by muse, mutect2, varscan2
- SPRR2D | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); catalogued as rs749847310, COSV100835992; called by muse, mutect2, varscan2
- SPTBN4 | c.2569G>T p.V857L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV100149832; called by muse, varscan2
- SPZ1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as rs775560121, COSV99698041; called by muse, mutect2, varscan2
- SRCAP | c.3995G>T p.R1332L | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV99349014; called by muse, mutect2, varscan2
- SRMS | c.1149C>A p.S383R | Missense Mutation (SNP) | VAF 270/345 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV99420231; called by muse, mutect2, varscan2
- SSBP1 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519658; called by muse, mutect2
- ST3GAL3 | c.194G>T p.G65V (on ENST00000361392 / NM_174964.4; = p.G50V on NM_006279.5) | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV99494818; called by muse, mutect2, varscan2
- ST8SIA6 | c.1131C>A p.S377R | Missense Mutation (SNP) | VAF 248/440 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101111982; called by muse, mutect2, varscan2
- ST8SIA6 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV66461752; called by muse, mutect2
- SYT10 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57340683, COSV99950875; called by muse, mutect2, varscan2
- SYT14 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99654379; called by muse, mutect2, varscan2
- TAF1L | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99644010; called by muse, mutect2, varscan2
- TARS1 | c.1450C>G p.R484G | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99465397; called by muse, mutect2, varscan2
- TAT | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.304); catalogued as COSV100587459; called by muse, mutect2, varscan2
- TCF4 | c.790-1G>T p.X264_splice | Splice Site (SNP) | VAF 25/101 reads (25%) | catalogued as COSV100609010; called by muse, mutect2, varscan2
- TCOF1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100076713; called by muse, mutect2, varscan2
- TECRL | c.878G>T p.W293L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV101168301; called by muse, mutect2, varscan2
- TENM1 | c.3768T>A p.N1256K | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV100948860; called by muse, mutect2, varscan2
- TENM1 | c.3767A>T p.N1256I | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100948861; called by muse, mutect2, varscan2
- TET2 | c.2861G>C p.W954S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV54414581, COSV54430677, COSV99480424; called by muse, mutect2, varscan2
- TFCP2 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99227425; called by muse, mutect2, varscan2
- THADA | c.4259C>A p.S1420Y | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100367743; called by muse, mutect2, varscan2
- THRAP3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100663138; called by muse, mutect2
- TLR4 | c.1507C>A p.L503I (on ENST00000355622 / NM_138554.5; = p.L463I on NM_003266.4) | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV100842627; called by muse, mutect2, varscan2
- TMEM131 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99486291; called by muse, mutect2, varscan2
- TMEM132B | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100168259, COSV54743515; called by muse, mutect2, varscan2
- TMEM132E | c.729-1G>C p.X243_splice (on ENST00000321639; = p.X333_splice on NM_001304438.2) | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100395890; called by muse, mutect2, varscan2
- TMEM38B | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101016138; called by muse, mutect2, varscan2
- TMEM41A | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99956486; called by muse, mutect2, varscan2
- TMEM67 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 87/380 reads (23%) | catalogued as COSV100018491; called by muse, mutect2, varscan2
- TMPRSS15 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99516662; called by muse, mutect2, varscan2
- TPO | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV61095558; called by muse, mutect2, varscan2
- TRIM42 | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV99647885; called by muse, mutect2, varscan2
- TRIM55 | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 12/165 reads (7%) | catalogued as COSV99396438; called by muse, mutect2
- TRPA1 | c.2295G>C p.T765= | Splice Region (SNP) | VAF 15/175 reads (9%) | catalogued as COSV100082919, COSV100085114; called by muse, mutect2
- TRPM1 | c.1896G>C p.W632C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99855209; called by muse, mutect2, varscan2
- TRPM8 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100223492; called by muse, mutect2
- TTBK1 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99443557; called by muse, mutect2, varscan2
- TTC21B | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); catalogued as rs754751728, COSV54629539, COSV54634143; called by muse, mutect2, varscan2
- TTC3 | c.4079A>C p.Q1360P | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100694923; called by muse, mutect2, varscan2
- TTN | c.17305C>A p.L5769I (on ENST00000591111; = p.L4842I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | PolyPhen benign (0.003); catalogued as rs1160746683, COSV100591361; called by muse, mutect2, varscan2
- UBR5 | c.869G>T p.R290M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99639010; called by muse, mutect2, varscan2
- UGT2B4 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100522149; called by muse, varscan2
- UHRF1BP1L | c.4210G>T p.G1404W | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99691000; called by muse, mutect2, varscan2
- USH2A | c.3311C>G p.P1104R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs778168432, COSV100228064; called by muse, mutect2, varscan2
- USH2A | c.701A>C p.H234P | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV100228066; called by muse, mutect2, varscan2
- USP9X | c.1721G>C p.R574T | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100198370; called by muse, mutect2, varscan2
- VCAN | c.2471C>G p.S824* | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | catalogued as COSV99424388; called by muse, mutect2, varscan2
- VIL1 | c.1909C>G p.P637A | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99945172; called by muse, mutect2, varscan2
- VPS13B | c.4156A>T p.S1386C | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV100660632; called by muse, mutect2, varscan2
- VWC2 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61484786, COSV99080281; called by muse, mutect2, varscan2
- WAPL | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99556237; called by muse, mutect2, varscan2
- WASF1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99660997; called by muse, mutect2, varscan2
- WNT11 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490209; called by muse, mutect2, varscan2
- WWP1 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV99615476; called by muse, mutect2
- ZAN | c.4983C>G p.S1661R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100769032; called by muse, mutect2, varscan2
- ZBTB41 | c.841A>T p.N281Y | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100962755; called by muse, mutect2, varscan2
- ZFHX4 | c.1228G>T p.G410W | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV99255012; called by muse, mutect2
- ZFHX4 | c.3847G>A p.V1283M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1433481502, COSV99255016; called by muse, mutect2
- ZFHX4 | c.8698G>C p.E2900Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50810800, COSV99255019; called by muse, mutect2, varscan2
- ZFP64 | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as COSV99401858; called by muse, mutect2, varscan2
- ZFPM2 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV101022936; called by muse, mutect2, varscan2
- ZNF208 | c.3409G>T p.G1137* | Nonsense Mutation (SNP) | VAF 43/91 reads (47%) | catalogued as COSV101236694; called by muse, mutect2, varscan2
- ZNF276 | c.334G>T p.V112L (on ENST00000443381 / NM_001113525.2; = p.V37L on NM_152287.4) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.508); catalogued as COSV99234485, COSV99235269; called by muse, mutect2, varscan2
- ZNF280A | c.1203C>A p.Y401* | Nonsense Mutation (SNP) | VAF 34/206 reads (17%) | catalogued as COSV100130928; called by muse, mutect2, varscan2
- ZNF280B | c.1501G>T p.V501F | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100840157; called by muse, mutect2, varscan2
- ZNF311 | c.642del p.C215Afs*14 | Frame Shift Del (DEL) | VAF 23/178 reads (13%) | catalogued as COSV101014052; called by mutect2, pindel, varscan2
- ZNF423 | c.2506G>A p.E836K (on ENST00000563137 / NM_001379286.1; = p.E828K on NM_015069.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.437); catalogued as COSV52203657; called by muse, mutect2, varscan2
- ZNF479 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV100482404; called by muse, mutect2, varscan2
- ZNF585B | c.1414G>T p.G472W | Missense Mutation (SNP) | VAF 117/200 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57214825; called by muse, mutect2, varscan2
- ZNF622 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100432965, COSV58073551; called by muse, mutect2, varscan2
- ZNF777 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99924938; called by muse, mutect2, varscan2
- ZNF827 | c.2665G>C p.D889H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as COSV101061083; called by muse, mutect2, varscan2
- ZRANB2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 32/102 reads (31%) | catalogued as COSV99638879; called by muse, mutect2, varscan2
- ABCB1 | c.1633del p.L545Wfs*40 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- ATG2A | c.5770del p.H1924Tfs*53 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- CD163 | c.2093_2094delinsA p.L698* | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by pindel, varscan2*
- COL10A1 | c.873del p.P293Qfs*14 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- CORO1A | c.496del p.A166Pfs*3 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- CR1 | c.483_484del p.C161* | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | called by pindel, varscan2
- DIDO1 | c.1849del p.A617Hfs*22 | Frame Shift Del (DEL) | VAF 38/221 reads (17%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.1037dup p.Q347Afs*52 | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- GAGE2E | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 37/1029 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGKV1D-17 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGKV6D-41 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KCNJ15 | c.341_342del p.L114Hfs*43 | Frame Shift Del (DEL) | VAF 49/152 reads (32%) | called by pindel, varscan2
- KIAA0100 | c.5425del p.E1809Sfs*31 | Frame Shift Del (DEL) | VAF 46/121 reads (38%) | called by mutect2, pindel, varscan2
- PTPN20 | c.777A>T p.E259D | Missense Mutation (SNP) | VAF 187/393 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAAL1 | c.1227G>T p.Q409H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2
- TBC1D3F | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TOPORS | c.113del p.G38Dfs*30 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- TRBC2 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ZFP64 | c.1309del p.E437Rfs*22 | Frame Shift Del (DEL) | VAF 13/141 reads (9%) | called by mutect2, pindel
- ZNF318 | c.3181dup p.Y1061Lfs*2 | Frame Shift Ins (INS) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- ABCA8 | c.24G>T p.V8= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV99284534; called by muse, mutect2, varscan2
- ACACB | c.276A>C p.L92= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as COSV100622206; called by muse, mutect2, varscan2
- ADAMTS8 | c.1230C>A p.A410= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs959037810, COSV99960250; called by muse, mutect2, varscan2
- ADGRL3 | c.3189G>T p.V1063= (on ENST00000506720 / NM_001322402.2; = p.V995= on NM_015236.6) | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as COSV101546800; called by muse, mutect2, varscan2
- AL121899.2 | c.2109G>A p.K703= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1433045815, COSV101198366; called by muse, mutect2, varscan2
- ALPP | c.1464C>A p.A488= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV101235057; called by muse, mutect2, varscan2
- ANK1 | c.306C>T p.A102= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV99223647; called by muse, mutect2, varscan2
- ANO4 | c.1812G>T p.L604= (on ENST00000392977 / NM_001286615.2; = p.L569= on NM_178826.4) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100151625, COSV54597848; called by muse, mutect2, varscan2
- ANO7 | c.756C>T p.S252= (on ENST00000274979; = p.S198= on NM_001370694.2) | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs377672810; called by muse, mutect2, varscan2
- AQP7 | c.261C>A p.R87= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99951555; called by muse, mutect2, varscan2
- ASAP1 | c.2004G>A p.Q668= | Silent (SNP) | VAF 20/277 reads (7%) | catalogued as COSV100726764; called by muse, mutect2
- ASAP1 | c.423C>T p.H141= | Silent (SNP) | VAF 70/347 reads (20%) | catalogued as COSV100726765; called by muse, mutect2, varscan2
- ASTN2 | c.549G>T p.L183= | Silent (SNP) | VAF 86/164 reads (52%) | catalogued as COSV57794119; called by muse, mutect2, varscan2
- ATP12A | c.789G>T p.T263= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as COSV54511897; called by muse, mutect2, varscan2
- CAMK2D | c.1071G>A p.L357= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99593056; called by muse, mutect2, varscan2
- CARD11 | c.2316G>C p.S772= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100829067, COSV62754031; called by muse, mutect2, varscan2
- CAT | c.474C>T p.P158= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99573065; called by muse, mutect2, varscan2
- CCDC158 | c.2388A>T p.R796= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV101187134; called by muse, mutect2, varscan2
- CCHCR1 | c.1632G>T p.L544= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99458540; called by muse, mutect2, varscan2
- CD109 | c.93A>T p.T31= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as COSV99752369; called by muse, mutect2, varscan2
- CDH2 | c.1473A>T p.V491= | Silent (SNP) | VAF 86/189 reads (46%) | catalogued as COSV99295355; called by muse, mutect2, varscan2
- CDK15 | c.714C>A p.L238= (on ENST00000652192 / NM_001366386.2; = p.L187= on NM_139158.2) | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV99642580; called by muse, mutect2, varscan2
- CFHR5 | c.579G>A p.G193= | Silent (SNP) | VAF 78/209 reads (37%) | catalogued as COSV56820870; called by muse, varscan2
- CLVS1 | c.117C>A p.R39= | Silent (SNP) | VAF 23/198 reads (12%) | catalogued as COSV100369336; called by muse, mutect2, varscan2
- CNTF | c.21A>T p.S7= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100284285; called by muse, mutect2, varscan2
- CNTN5 | c.2298C>A p.I766= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs550988442; called by muse, mutect2
- COL23A1 | c.633C>A p.G211= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV101177917; called by muse, mutect2, varscan2
- CSMD3 | c.5328A>T p.P1776= (on ENST00000297405 / NM_001363185.1; = p.P1672= on NM_052900.3) | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as COSV99822286; called by muse, mutect2, varscan2
- CTLA4 | c.276G>T p.G92= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV99865050; called by muse, mutect2, varscan2
- DDI1 | c.240G>T p.V80= | Silent (SNP) | VAF 84/297 reads (28%) | catalogued as COSV100157542; called by muse, mutect2, varscan2
- DENND3 | c.558C>A p.I186= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as COSV99370216; called by muse, mutect2
- DIAPH2 | c.2256G>T p.V752= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61298428; called by muse, mutect2
- DPF2 | c.378C>T p.D126= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs760874409, COSV99361300; called by muse, mutect2, varscan2
- DRD3 | c.756G>T p.L252= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as COSV99879108; called by muse, mutect2, varscan2
- EFNA5 | c.345T>C p.S115= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100320728; called by muse, mutect2, varscan2
- ENDOD1 | c.1389C>G p.V463= | Silent (SNP) | VAF 64/207 reads (31%) | catalogued as COSV99566281; called by muse, mutect2, varscan2
- ENPP1 | c.1611T>A p.S537= | Silent (SNP) | VAF 95/197 reads (48%) | catalogued as COSV100719338; called by muse, mutect2, varscan2
- EPHB1 | c.1179C>T p.I393= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV101212563; called by muse, mutect2, varscan2
- F13A1 | c.1521C>A p.L507= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99341973; called by muse, mutect2
- FAM177B | c.423G>C p.G141= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs766077031, COSV100680246; called by muse, varscan2
- FAM47A | c.849G>T p.R283= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV100649676; called by muse, mutect2, varscan2
- FGF21 | c.21G>T p.G7= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99711338; called by muse, mutect2, varscan2
- FIBCD1 | c.1215C>T p.Y405= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99446597; called by muse, mutect2, varscan2
- FLI1 | c.771G>T p.R257= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV55644636, COSV99857305; called by muse, mutect2, varscan2
- FLVCR2 | c.1248T>C p.T416= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs777838404, COSV53162891; called by muse, mutect2, varscan2
- FSIP2 | c.16248C>A p.T5416= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as COSV100553651; called by muse, mutect2, varscan2
- GFRA2 | c.393G>T p.V131= | Silent (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- GJA8 | c.1068G>C p.L356= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs782436434, COSV99569032; called by muse, mutect2, varscan2
- GMIP | c.2829A>G p.L943= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99179065; called by muse, mutect2, varscan2
- GPC3 | c.255A>T p.A85= | Silent (SNP) | VAF 69/255 reads (27%) | catalogued as COSV100892602; called by muse, mutect2, varscan2
- GPR78 | c.81G>T p.L27= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101223910; called by muse, mutect2, varscan2
- GRIN2B | c.4239G>T p.G1413= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101662874; called by muse, mutect2, varscan2
- H3C7 | c.330G>C p.L110= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV99768995; called by muse, mutect2, varscan2
- HAS2 | c.1347C>T p.P449= | Silent (SNP) | VAF 60/630 reads (10%) | catalogued as rs1394305829, COSV100392186; called by muse, mutect2
- HECTD4 | c.5511A>G p.Q1837= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101106560; called by muse, mutect2, varscan2
- HECW1 | c.4254G>C p.T1418= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV101222625, COSV67827355; called by muse, mutect2, varscan2
- HOXA7 | c.573C>T p.D191= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as COSV99636181; called by muse, mutect2, varscan2
- HRH3 | c.327G>T p.L109= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100420411; called by muse, mutect2
- HTR1A | c.687G>A p.T229= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as COSV100108865, COSV60500045; called by muse, mutect2, varscan2
- HTR1B | c.945C>A p.T315= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as rs1401107411, COSV100885305; called by muse, mutect2, varscan2
- IL17A | c.162G>T p.R54= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as COSV100391383; called by muse, mutect2, varscan2
- IL21R | c.234C>A p.T78= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs770949831, COSV100559759; called by muse, mutect2, varscan2
- ITPR2 | c.3159A>G p.G1053= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV101189778; called by muse, mutect2, varscan2
- JUNB | c.234G>C p.A78= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV100040064; called by muse, mutect2, varscan2
- KCNA2 | c.783G>T p.V261= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100315794; called by muse, mutect2, varscan2
- KCNK9 | c.1086C>A p.T362= | Silent (SNP) | VAF 85/233 reads (36%) | catalogued as rs760537472, COSV100270186; called by muse, mutect2, varscan2
- KCNV1 | c.1365C>A p.T455= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as COSV52087839, COSV99818826; called by muse, mutect2, varscan2
- KRT6A | c.441C>T p.P147= | Silent (SNP) | VAF 44/222 reads (20%) | catalogued as rs1238917329, COSV100416643; called by muse, mutect2, varscan2
- LARGE2 | c.1392A>C p.T464= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99138017; called by muse, mutect2, varscan2
- LILRA2 | c.282G>T p.R94= | Silent (SNP) | VAF 75/121 reads (62%) | catalogued as COSV99252590; called by muse, mutect2, varscan2
- LRP4 | c.1398C>T p.N466= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1473827509, COSV101066134; called by muse, mutect2
- MAGEB16 | c.486A>T p.L162= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV101303264, COSV67874614; called by muse, mutect2, varscan2
- MAGI1 | c.4098C>T p.S1366= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs1459620289, COSV100439038; called by muse, mutect2, varscan2
- MAP1B | c.339C>A p.I113= | Silent (SNP) | VAF 57/103 reads (55%) | catalogued as COSV99701669; called by muse, mutect2, varscan2
- MCM2 | c.1392C>A p.I464= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as COSV99412705; called by muse, mutect2, varscan2
- MCOLN2 | c.1443G>C p.L481= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs566878730, COSV99393542; called by muse, mutect2, varscan2
- MED23 | c.300C>T p.S100= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100644698; called by muse, mutect2, varscan2
- MELK | c.1423C>T p.L475= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV99974154; called by muse, mutect2, varscan2
- MROH2B | c.3973C>A p.R1325= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV101270442, COSV68181161; called by muse, mutect2, varscan2
- MUC16 | c.4614C>T p.T1538= | Silent (SNP) | VAF 115/207 reads (56%) | catalogued as rs775989202, COSV101197731; called by muse, mutect2, varscan2
- MYO18B | c.297T>A p.P99= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100122399, COSV100125545; called by muse, mutect2, varscan2
- NBEA | c.1711C>T p.L571= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs1472602939; called by muse, mutect2, varscan2
- NCK2 | c.261G>A p.R87= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99255077; called by muse, mutect2, varscan2
- NDE1 | c.1089T>C p.A363= (on ENST00000577101; = p.*336Rext*11 on NM_017668.3) | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100257500; called by muse, mutect2, varscan2
- NEB | c.7083G>T p.V2361= | Silent (SNP) | VAF 342/526 reads (65%) | catalogued as COSV99414020; called by muse, mutect2, varscan2
- NEU1 | c.1161C>A p.P387= | Silent (SNP) | VAF 10/195 reads (5%) | catalogued as COSV99998534; called by muse, mutect2
- NID1 | c.675A>G p.S225= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as COSV99936891; called by muse, mutect2, varscan2
- NOS1 | c.2191C>A p.R731= | Silent (SNP) | VAF 109/197 reads (55%) | catalogued as COSV100499918, COSV57607748; called by muse, mutect2
- NRG1 | c.1293G>T p.P431= (on ENST00000405005 / NM_013964.5; = p.P436= on NM_013956.5) | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV55170633, COSV99827347; called by muse, mutect2, varscan2
- OLFML1 | c.756C>A p.L252= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100205841; called by muse, mutect2, varscan2
- OR2AK2 | c.897G>A p.G299= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as COSV100823025; called by muse, mutect2, varscan2
- OR2T2 | c.504C>A p.P168= | Silent (SNP) | VAF 21/337 reads (6%) | catalogued as COSV100737531; called by muse, mutect2
- OR51B5 | c.222C>A p.T74= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100332386; called by muse, mutect2, varscan2
- OR5D16 | c.921C>A p.I307= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV65722712; called by muse, mutect2, varscan2
- OR5J2 | c.405C>A p.A135= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV56622167; called by muse, mutect2
- OR6B1 | c.54T>A p.P18= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV101281630; called by muse, mutect2, varscan2
- OR8K3 | c.468T>C p.S156= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1565108504, COSV100449635, COSV100449880; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2277C>T p.S759= (on ENST00000259318 / NM_001136562.3; = p.S990= on NM_007203.5) | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99394609; called by muse, mutect2, varscan2
- PCDH17 | c.3219C>T p.P1073= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100931386; called by muse, mutect2, varscan2
- PCK2 | c.639C>T p.S213= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs890165002, COSV99394051; called by muse, mutect2, varscan2
- PDP1 | c.408A>G p.R136= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV99891846; called by muse, mutect2, varscan2
- PFN4 | c.30C>T p.D10= | Silent (SNP) | VAF 95/147 reads (65%) | catalogued as COSV57531023; called by muse, mutect2, varscan2
- PLCG2 | c.1749C>G p.V583= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV100842026; called by muse, mutect2, varscan2
- PRSS16 | c.1302T>C p.P434= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV100041485; called by muse, mutect2, varscan2
- PTPRD | c.2397C>T p.T799= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs145034888; called by muse, mutect2, varscan2
- RFC5 | c.162A>G p.P54= | Silent (SNP) | VAF 86/175 reads (49%) | catalogued as COSV99969735; called by muse, mutect2, varscan2
- RHAG | c.852C>A p.G284= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100006242; called by muse, mutect2, varscan2
- RIF1 | c.2826G>T p.V942= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV99689940; called by muse, mutect2, varscan2
- RP1L1 | c.1113C>A p.G371= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV101222887; called by muse, mutect2, varscan2
- RPRD1B | c.762G>A p.L254= | Silent (SNP) | VAF 94/263 reads (36%) | catalogued as COSV100987141; called by muse, mutect2, varscan2
- SATL1 | c.1269C>A p.G423= (on ENST00000395409; = p.G610= on NM_001012980.2) | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV100260634; called by muse, mutect2, varscan2
- SCN5A | c.1839C>A p.S613= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100346122; called by muse, mutect2, varscan2
- SDK1 | c.2733G>T p.P911= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV101268660; called by muse, mutect2, varscan2
- SEMA6D | c.2919T>C p.S973= (on ENST00000316364 / NM_153618.2; = p.S911= on NM_020858.2) | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV100316320; called by muse, mutect2, varscan2
- SERPINB4 | c.273A>G p.E91= | Silent (SNP) | VAF 47/186 reads (25%) | catalogued as COSV100345371; called by muse, mutect2, varscan2
- SEZ6L2 | c.1449A>T p.P483= (on ENST00000308713 / NM_001114099.3; = p.P413= on NM_012410.4) | Silent (SNP) | VAF 73/172 reads (42%) | catalogued as COSV100435005; called by muse, mutect2, varscan2
- SHISA2 | c.492C>A p.I164= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100096218, COSV100096412; called by muse, mutect2, varscan2
- SLC13A2 | c.837G>T p.L279= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100120017; called by muse, mutect2, varscan2
- SLC22A12 | c.738C>A p.G246= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100327291; called by muse, mutect2, varscan2
- SLC4A10 | c.2010G>T p.V670= (on ENST00000446997 / NM_001354461.2; = p.V640= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV99762033; called by muse, mutect2, varscan2
- SPON2 | c.90G>A p.G30= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99335063; called by muse, mutect2, varscan2
- STK31 | c.2115G>A p.L705= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV100669061; called by muse, mutect2, varscan2
- STYK1 | c.462G>A p.G154= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99311524; called by muse, mutect2, varscan2
- SURF4 | c.190C>T p.L64= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1463125501, COSV100915161; called by muse, mutect2, varscan2
- SYNE1 | c.11796A>G p.Q3932= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV99551007; called by muse, mutect2, varscan2
- TENM2 | c.2319C>T p.R773= (on ENST00000518659 / NM_001122679.2; = p.R541= on NM_001080428.3) | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV101317593; called by muse, mutect2
- THSD7B | c.357C>T p.Y119= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs1455127441, COSV55663354; called by muse, mutect2, varscan2
- TMCC2 | c.351T>C p.H117= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs754198015, COSV100404955; called by muse, mutect2, varscan2
- TMEM200A | c.495C>A p.S165= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV99758557; called by muse, mutect2, varscan2
- TMEM266 | c.1059C>A p.T353= | Silent (SNP) | VAF 41/184 reads (22%) | catalogued as rs1333060934, COSV101189548; called by muse, mutect2, varscan2
- TNFRSF13C | c.318G>T p.R106= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99351647; called by muse, mutect2, varscan2
- TNRC6B | c.3807G>C p.L1269= (on ENST00000454349 / NM_001162501.2; = p.L1159= on NM_015088.3) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100108858; called by muse, mutect2, varscan2
- TRAJ41 | c.48G>A p.S16= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs145922690; called by muse, mutect2, varscan2
- TRBC2 | c.342C>A p.A114= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.78C>A p.I26= | Silent (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2
- TRPA1 | c.78G>C p.P26= | Silent (SNP) | VAF 32/332 reads (10%) | catalogued as rs746121998, COSV100082921; called by muse, mutect2, varscan2
- TRPC4 | c.1731G>C p.G577= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100155629; called by muse, mutect2, varscan2
- USP31 | c.756C>A p.G252= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV99564500; called by muse, mutect2, varscan2
- VANGL2 | c.657C>T p.A219= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs779755960, COSV63604052; called by muse, mutect2, varscan2
- WDR7 | c.135C>T p.L45= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV99588282; called by muse, mutect2, varscan2
- XIRP2 | c.1605G>T p.V535= (on ENST00000628543; = p.V710= on NM_152381.6) | Silent (SNP) | VAF 69/108 reads (64%) | catalogued as COSV99737522; called by muse, mutect2, varscan2
- ZHX1 | c.2232G>T p.G744= | Silent (SNP) | VAF 71/340 reads (21%) | catalogued as COSV99933433; called by muse, mutect2, varscan2
- ZNF394 | c.69G>T p.A23= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100459983, COSV100460089, COSV58742402; called by muse, mutect2, varscan2
- ZNF613 | c.21A>T p.S7= | Silent (SNP) | VAF 91/169 reads (54%) | catalogued as COSV99522822, COSV99522941; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097418 C>T | 3'Flank (SNP) | VAF 73/585 reads (12%) | catalogued as rs759784994, COSV100800840; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823596 A>T | 5'Flank (SNP) | VAF 26/104 reads (25%) | catalogued as rs1435943426; called by muse, mutect2
- C3P1 | n.2473C>A | RNA (SNP) | VAF 60/129 reads (47%) | called by muse, mutect2, varscan2
- FAM124B | c.-2C>A | 5'UTR (SNP) | VAF 25/47 reads (53%) | catalogued as COSV99706115; called by muse, mutect2, varscan2
- IGKV1-13 | n.305C>A | RNA (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- KLRA1P | n.171G>T | RNA (SNP) | VAF 62/240 reads (26%) | called by muse, mutect2, varscan2
- LILRB5 | c.*2C>A | 3'UTR (SNP) | VAF 44/78 reads (56%) | catalogued as COSV100299994, COSV60257482; called by muse, mutect2, varscan2
- MIR124-2 | n.22C>A | RNA (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- MIR519B | n.9G>T | RNA (SNP) | VAF 109/182 reads (60%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8026+2918A>T | Intron (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100629002; called by muse, mutect2, varscan2
- PITPNM2 | c.2404+732G>T | Intron (SNP) | VAF 17/27 reads (63%) | catalogued as COSV99758137; called by muse, mutect2, varscan2
- TRIM10 | c.*225G>T | 3'UTR (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100939582; called by muse, mutect2, varscan2
- TRPM3 | c.184-256714C>T | Intron (SNP) | VAF 14/75 reads (19%) | catalogued as COSV62702385; called by muse, mutect2, varscan2
- TRPM3 | c.184-256715C>T | Intron (SNP) | VAF 13/74 reads (18%) | catalogued as rs1299375898, COSV100623866; called by muse, mutect2, varscan2
- USH1C | c.1285-3959del | Intron (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- XIST | n.10025C>T | RNA (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
